CCDI case PBCJEP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/7be3dd32-7abe-4b8d-b8da-3ad0a7817d92

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 8.3 years (3,040 days).

Biospecimens (3 samples)
- Sample 0DU7ZM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU803: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DU814: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
